Gene-level copy-number profile of specimen HCM-BROD-0960-C16-85A from HCMI case HCM-BROD-0960-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 64.5 years (23,555 days).
Specimen HCM-BROD-0960-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e0e9389-6bec-40f6-924e-4ef94737e501.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0960-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/f0108beb-eb5a-4bd7-b628-f8d2e21d1ecd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 5,035; copy number 2: 48,327; copy number 3: 4,413; copy number 4: 1,104; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,025,511–22,101,360, 1 gene (within-gene range 0–1): CDC42.
- chr1:22,059,197–22,068,827, 2 genes: CDC42-IT1, MPHOSPH6P1.
- chr3:4,303,304–4,493,163, 3 genes (within-gene range 0–2): SETMAR, MRPS10P2, ITPR1-DT.
- chr5:59,039,761–59,314,800, 2 genes (within-gene range 0–2): AC092343.1, AC008833.1.
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr7:5,419,827–5,429,672, 5 genes (within-gene range 0–1): AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:73,054,976–73,113,018, 3 genes, copy number 5: KLF5, FABP5P1, RNU6-66P.

Autosomal genes at a single copy (total copy number 1): 2,179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
